Somatic mutation profile of tumor specimen TCGA-AA-3506-01A (aliquot TCGA-AA-3506-01A-01D-2188-10) from TCGA case TCGA-AA-3506, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 77.4 years (28,275 days).
Specimen TCGA-AA-3506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c3b8f64-0ae8-4428-847e-f10962133716.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3506-11A (Solid Tissue Normal), aliquot TCGA-AA-3506-11A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88a1b186-9a2e-4502-8737-60caf49860b9

The open-access MAF lists 175 somatic variants for this specimen: 125 protein-altering or splice-affecting, 49 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 49, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 51/180 reads (28%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 125/239 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.1487T>C p.L496S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100741916; called by muse, mutect2, varscan2
- ABI3BP | c.3193C>A p.P1065T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99428889; called by muse, mutect2, varscan2
- ACVR2A | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 57/107 reads (53%) | catalogued as COSV54019853; called by muse, mutect2, varscan2
- ADRA2B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV101337397; called by muse, mutect2, varscan2
- ALPI | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758104990, COSV55015130; called by muse, mutect2, varscan2
- AMER1 | c.1413T>G p.Y471* | Nonsense Mutation (SNP) | VAF 114/157 reads (73%) | catalogued as COSV100367173; called by muse, mutect2, varscan2
- AMPD3 | c.959C>T p.A320V (on ENST00000396553 / NM_001025389.2; = p.A329V on NM_000480.3) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs147542803, CM940054; called by muse, mutect2, varscan2
- ANK2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763603177, COSV100004698; called by muse, mutect2, varscan2
- ANKFY1 | c.1382T>C p.L461S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100493282; called by muse, mutect2, varscan2
- ATP8A2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs982621651, COSV54949944; called by muse, mutect2, varscan2
- ATXN7 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as rs201198489; called by muse, mutect2, varscan2
- C12orf4 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs774878836, COSV99713005; called by muse, mutect2, varscan2
- CARMIL3 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754544491, COSV100549942; called by muse, mutect2, varscan2
- CCNA1 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1249425100, COSV99715013; called by muse, mutect2, varscan2
- CCR7 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs764245161, COSV55848452, COSV99878856; called by muse, mutect2
- CDH9 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs141440884; called by muse, mutect2, varscan2
- CEACAM3 | c.627G>A p.S209= | Splice Region (SNP) | VAF 26/146 reads (18%) | catalogued as rs565000338, COSV55761179; called by muse, mutect2, varscan2
- CFAP65 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs760496355, COSV58562117; called by muse, mutect2, varscan2
- CHRM4 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as rs1458794885, COSV63127629; called by muse, mutect2, varscan2
- CLEC4D | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100223216; called by muse, mutect2, varscan2
- CNTFR | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as rs758772223, COSV63633123; called by muse, mutect2, varscan2
- CNTNAP2 | c.2840T>G p.L947R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100673817; called by muse, mutect2, varscan2
- COL4A4 | c.3920G>A p.G1307D | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307964; called by muse, mutect2, varscan2
- CPXM2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.025); catalogued as COSV99583548; called by muse, mutect2, varscan2
- CRYBG3 | c.5910A>G p.I1970M | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs766737642, COSV51710247; called by muse, mutect2, varscan2
- CSMD2 | c.6073C>T p.R2025W | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs199995969, COSV53917921; called by muse, mutect2, varscan2
- DMXL2 | c.3011C>A p.S1004* | Nonsense Mutation (SNP) | VAF 38/127 reads (30%) | catalogued as COSV51855853, COSV99198883; called by muse, mutect2, varscan2
- DNAI1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs752354598, COSV54280364, COSV54280621; called by muse, mutect2, varscan2
- DPF2 | c.899G>C p.R300P | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52890101, COSV52890894; called by muse, mutect2, varscan2
- DPPA2 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs757394035, COSV72117914; called by muse, mutect2, varscan2
- DYRK1B | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.722); catalogued as rs753581092, COSV59913874; called by muse, mutect2, varscan2
- EPS8L1 | c.1714C>T p.R572C (on ENST00000201647 / NM_133180.3; = p.R445C on NM_017729.3) | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as rs1017401421, COSV52381059; called by muse, mutect2, varscan2
- ESPL1 | c.4940G>A p.R1647Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749239351, COSV57757011; called by muse, mutect2, varscan2
- FA2H | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548022; called by muse, mutect2, varscan2
- FAM47A | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 114/291 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs781481848, COSV100650125, COSV60496194; called by muse, mutect2, varscan2
- FANCA | c.2015-1G>T p.X672_splice | Splice Site (SNP) | VAF 34/97 reads (35%) | catalogued as CS050800, COSV101225309; called by muse, mutect2, varscan2
- FCSK | c.1280C>T p.T427M | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs376353924, COSV55368426; called by muse, mutect2, varscan2
- FGD2 | c.1392C>A p.C464* | Nonsense Mutation (SNP) | VAF 38/110 reads (35%) | catalogued as COSV99236790; called by muse, mutect2, varscan2
- FZD2 | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.122); catalogued as rs148517314; called by muse, mutect2
- GABRA1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1457242041, COSV50098975; called by muse, mutect2, varscan2
- GANC | c.2594G>A p.G865D | Missense Mutation (SNP) | VAF 31/82 reads (38%) | PolyPhen probably damaging (0.995); catalogued as COSV100531325; called by muse, mutect2, varscan2
- GATA3 | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60520375; called by muse, mutect2, varscan2
- GIGYF1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs759529912, COSV99310174; called by muse, mutect2, varscan2
- GRIN2A | c.2815G>A p.G939R | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV100411331; called by muse, mutect2, varscan2
- GRIP2 | c.2309C>T p.T770M (on ENST00000619221; = p.T673M on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs774195468, COSV56123964; called by muse, mutect2, varscan2
- HYDIN | c.7522C>T p.R2508C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs773554347, COSV99993984; called by muse, mutect2, varscan2
- IFT74 | c.1206+1G>A p.X402_splice | Splice Site (SNP) | VAF 45/139 reads (32%) | catalogued as COSV66286366; called by muse, mutect2, varscan2
- IGFBP1 | c.634T>C p.Y212H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747950009, COSV51874448; called by muse, mutect2, varscan2
- IL17RE | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs762873000, COSV55967474; called by muse, mutect2, varscan2
- INA | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760759982, COSV100878712, COSV100878717; called by muse, mutect2, varscan2
- KCNU1 | c.2603C>A p.P868H | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV67753474, COSV67754444; called by muse, mutect2, varscan2
- KIAA0319 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as COSV65499381; called by muse, mutect2, varscan2
- KIAA1109 | c.8423T>G p.F2808C | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs370801689; called by muse, mutect2, varscan2
- KIF24 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99903668; called by muse, mutect2, varscan2
- KRTAP4-2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs754307555, COSV66658212; called by muse, mutect2, varscan2
- LAMA2 | c.2008C>G p.R670G | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101370502, COSV101370942; called by muse, mutect2, varscan2
- LPAR5 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.645); catalogued as COSV61692592; called by muse, mutect2, varscan2
- MIGA2 | c.534G>T p.M178I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99477949; called by muse, mutect2, varscan2
- MSANTD2 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1395932704, COSV53448106; called by muse, mutect2
- MTUS2 | c.1736G>A p.R579H | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs541680231, COSV101462408, COSV70922491; called by muse, mutect2, varscan2
- NALCN | c.1266+1G>C p.X422_splice | Splice Site (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99218422; called by muse, mutect2, varscan2
- NIPBL | c.4607G>A p.R1536Q | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56958690; called by muse, mutect2, varscan2
- NLGN4Y | c.2288C>T p.T763M | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV59295025; called by muse, mutect2, varscan2
- NOL4 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs755854498, COSV52347295; called by muse, mutect2, varscan2
- NUP160 | c.3347G>A p.R1116Q | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs747949018, COSV65854113; called by muse, mutect2, varscan2
- OPRD1 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs1187638002, COSV52381200; called by muse, mutect2, varscan2
- OR51M1 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs776468666, COSV60783935; called by muse, mutect2
- OSM | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV53161027; called by muse, mutect2, varscan2
- PAPLN | c.1807C>A p.L603M (on ENST00000554301; = p.L576M on NM_173462.4) | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as rs1184507905, COSV53715457; called by muse, mutect2, varscan2
- PAX4 | c.28A>G p.N10D | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490383; called by muse, mutect2, varscan2
- PCARE | c.3479C>A p.A1160E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.288); catalogued as COSV100527994; called by muse, mutect2, varscan2
- PCDHA1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs368549830; called by muse, mutect2, varscan2
- PCDHA2 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 74/193 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as rs1396970768, COSV65364174; called by muse, mutect2, varscan2
- PCDHA9 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.223); catalogued as rs782628181, COSV65329248; called by muse, mutect2, varscan2
- PCDHGA12 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.014); catalogued as rs978782104, COSV99342874; called by muse, mutect2, varscan2
- PCDHGA8 | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53920620; called by muse, mutect2, varscan2
- PDCD10 | c.200T>C p.L67S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV101208564; called by muse, mutect2, varscan2
- PDE6A | c.1775T>G p.M592R | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99678809; called by muse, mutect2, varscan2
- PLEKHA3 | c.595T>C p.S199P | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV52293615; called by muse, mutect2, varscan2
- PLEKHH2 | c.3020T>C p.L1007S | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99175265; called by muse, mutect2, varscan2
- PNMA8B | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV66536133; called by muse, mutect2, varscan2
- POM121L12 | c.422T>G p.I141S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101374986, COSV101375002; called by muse, mutect2, varscan2
- PRAMEF12 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs752095583, COSV63215039; called by muse, mutect2, varscan2
- PWWP3A | c.1025G>C p.S342T (on ENST00000627377; = p.S341T on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as COSV100262323; called by muse, mutect2, varscan2
- RAD54L2 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs772693904, COSV104408593; called by muse, mutect2, varscan2
- RARS2 | c.1682C>A p.S561Y | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.012); catalogued as COSV101057511; called by muse, mutect2, varscan2
- RCBTB1 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs767930306, COSV51633822; called by muse, mutect2, varscan2
- RXRG | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.872); catalogued as rs200646455; called by muse, varscan2
- RYR2 | c.3478G>A p.D1160N | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1064794172, COSV63683718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.12436G>A p.E4146K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1349585791, CM045196, COSV63657666, COSV63700458; called by muse, mutect2, varscan2
- SAG | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs747018082, COSV68591428; called by muse, mutect2, varscan2
- SCAPER | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs372507166; called by muse, mutect2, varscan2
- SDK2 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1466911865, COSV101168927; called by muse, mutect2
- SLC29A3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as rs144183340; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A3 | c.3067G>A p.G1023S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56096260; called by muse, mutect2, varscan2
- SLC8A1 | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429813299, COSV100247653; called by muse, mutect2, varscan2
- SLTM | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV51056376; called by muse, mutect2, varscan2
- SMC2 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 52/192 reads (27%) | catalogued as COSV99659882; called by muse, mutect2, varscan2
- SOX9 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99818858; called by muse, mutect2, varscan2
- SPTA1 | c.5660A>G p.N1887S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100935753; called by muse, mutect2, varscan2
- SUCLA2 | c.1098C>G p.F366L (on ENST00000643023; = p.F345L on NM_003850.3) | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101074999, COSV66223349; called by muse, mutect2, varscan2
- SYNE1 | c.18746G>C p.R6249P (on ENST00000367255 / NM_182961.4; = p.R6178P on NM_033071.3) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV99583440; called by muse, mutect2, varscan2
- SYT14 | c.1565T>C p.L522S | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99656363; called by muse, mutect2, varscan2
- SYT3 | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs140892148; called by muse, mutect2, varscan2
- THRAP3 | c.2391A>C p.E797D | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.379); catalogued as COSV100663685; called by muse, mutect2, varscan2
- TMEM132E | c.1036C>T p.R346W (on ENST00000321639; = p.R436W on NM_001304438.2) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs141962331; called by muse, mutect2, varscan2
- TMEM54 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs746007733, COSV100232020; called by muse, mutect2, varscan2
- TRIM9 | c.1970dup p.N657Kfs*9 | Frame Shift Ins (INS) | VAF 34/142 reads (24%) | catalogued as rs1566537620; called by mutect2, pindel, varscan2
- TSKS | c.1719G>A p.M573I | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV55872492, COSV99883795; called by muse, mutect2, varscan2
- TTC24 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs756779555, COSV100964382; called by muse, mutect2, varscan2
- VWCE | c.2303G>A p.R768Q | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs541004294, COSV57113297; called by muse, mutect2, varscan2
- ZNF142 | c.5080C>T p.R1694C (on ENST00000411696 / NM_001379660.1; = p.R1494C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs762909383, COSV68743328; called by muse, mutect2, varscan2
- ZNF19 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as rs772806220, COSV99867774; called by muse, mutect2, varscan2
- ZNF302 | c.1370T>A p.F457Y (on ENST00000627982; = p.F378Y on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/149 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71063343; called by muse, mutect2, varscan2
- ZNF45 | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99524297; called by muse, mutect2, varscan2
- ZNF556 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs111290787, COSV56911704; called by muse, mutect2, varscan2
- ZNF582 | c.1382G>T p.S461I | Missense Mutation (SNP) | VAF 70/258 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.222); catalogued as COSV100019050; called by muse, mutect2, varscan2
- ZNF597 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs200879821; called by muse, mutect2, varscan2
- CHIA | c.935del p.N312Mfs*68 (on ENST00000343320; = p.N204Mfs*68 on NM_021797.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 32/146 reads (22%) | called by mutect2, pindel, varscan2
- ITPR3 | c.7744_7745del p.D2582Lfs*5 | Frame Shift Del (DEL) | VAF 38/145 reads (26%) | called by pindel, varscan2
- NR5A1 | c.382dup p.V128Gfs*21 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- RNPS1 | c.23del p.K8Rfs*5 | Frame Shift Del (DEL) | VAF 40/130 reads (31%) | called by mutect2, pindel, varscan2
- SOX9 | c.723del p.T243Pfs*10 | Frame Shift Del (DEL) | VAF 131/354 reads (37%) | called by mutect2, pindel, varscan2
- AATK | c.4026G>A p.A1342= (on ENST00000326724 / NM_001080395.3; = p.A1239= on NM_004920.2) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1259076952, COSV100353393; called by muse, mutect2, varscan2
- ADAM8 | c.456C>T p.H152= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs775423816, COSV101291762; called by muse, mutect2, varscan2
- ADAMTS5 | c.366G>A p.A122= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs375872938, COSV53185645; called by muse, mutect2, varscan2
- ANXA8 | c.501G>A p.R167= | Silent (SNP) | VAF 244/1380 reads (18%) | called by muse, mutect2, varscan2
- C16orf71 | c.447C>T p.G149= | Silent (SNP) | VAF 42/141 reads (30%) | catalogued as rs375548291; called by muse, mutect2, varscan2
- C3 | c.3057G>A p.T1019= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as rs749825273, COSV55568246; called by muse, mutect2, varscan2
- CNTNAP2 | c.1956C>G p.G652= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as COSV100673816; called by muse, mutect2, varscan2
- COL1A1 | c.2166C>A p.G722= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV99868335; called by muse, mutect2, varscan2
- COL27A1 | c.4836C>A p.P1612= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100621396; called by muse, varscan2
- DISP3 | c.3414G>A p.S1138= | Silent (SNP) | VAF 63/207 reads (30%) | catalogued as rs200270736, COSV53828949; called by muse, mutect2
- DST | c.21507C>T p.I7169= (on ENST00000361203 / NM_001374722.1; = p.I4866= on NM_015548.5) | Silent (SNP) | VAF 48/175 reads (27%) | catalogued as rs765285817, COSV55005521; called by muse, mutect2, varscan2
- EDEM1 | c.447C>T p.A149= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99849469; called by muse, mutect2, varscan2
- ESR1 | c.63C>T p.N21= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99241753; called by muse, mutect2, varscan2
- F3 | c.393G>A p.E131= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV61844795; called by muse, mutect2, varscan2
- FBXO39 | c.921G>A p.P307= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs764013991, COSV58620917; called by muse, mutect2, varscan2
- FREM1 | c.873G>A p.P291= | Silent (SNP) | VAF 41/132 reads (31%) | catalogued as rs772721697, COSV100772230, COSV63087310; called by muse, mutect2, varscan2
- HSD17B1 | c.633C>T p.H211= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV99864991; called by muse, mutect2, varscan2
- IGF1 | c.150G>A p.P50= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs373202198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IKZF4 | c.375C>T p.S125= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as rs756465793, COSV56267644; called by muse, mutect2, varscan2
- KIAA1841 | c.1428G>A p.P476= | Silent (SNP) | VAF 59/144 reads (41%) | catalogued as rs754421415, COSV99694299; called by muse, mutect2, varscan2
- KIR2DL3 | c.438C>T p.T146= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs776207961, COSV60896530; called by muse, mutect2, varscan2
- MTUS2 | c.616C>A p.R206= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV101462407; called by muse, mutect2, varscan2
- NEK10 | c.2643C>T p.D881= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as rs753032028, COSV55356888; called by muse, mutect2, varscan2
- NID2 | c.2622G>A p.T874= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs775891579, COSV53505341, COSV99356825; called by muse, mutect2, varscan2
- NLRP12 | c.558C>T p.T186= | Silent (SNP) | VAF 50/239 reads (21%) | catalogued as rs750215766, COSV100146046; called by muse, mutect2, varscan2
- NRXN1 | c.3795C>A p.G1265= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV60487296, COSV60491037, COSV60506619; called by muse, mutect2, varscan2
- NTN3 | c.732C>T p.Y244= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1200869176, COSV53546793; called by muse, mutect2, varscan2
- NXF3 | c.933C>G p.G311= | Silent (SNP) | VAF 74/106 reads (70%) | catalogued as COSV67703112; called by muse, mutect2, varscan2
- PCDHB15 | c.2220C>T p.S740= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV99179305; called by muse, mutect2, varscan2
- PCDHGC5 | c.2160C>T p.N720= | Silent (SNP) | VAF 48/140 reads (34%) | catalogued as COSV99342879; called by muse, varscan2
- PLEKHG5 | c.642C>T p.T214= (on ENST00000400915 / NM_001042663.3; = p.T177= on NM_020631.6) | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs567059799, COSV61700591; called by muse, mutect2, varscan2
- PROS1 | c.834T>C p.D278= | Silent (SNP) | VAF 98/329 reads (30%) | catalogued as rs1470771749, COSV101260914; called by muse, varscan2
- PTPN13 | c.942T>C p.S314= | Silent (SNP) | VAF 49/179 reads (27%) | catalogued as COSV100365584; called by muse, mutect2, varscan2
- RAB6C | c.279C>T p.Y93= | Silent (SNP) | VAF 73/232 reads (31%) | catalogued as rs756654638, COSV69339376; called by muse, mutect2, varscan2
- RNF113B | c.273C>T p.D91= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs775287438, COSV99940444; called by muse, mutect2, varscan2
- RTN4RL1 | c.615C>T p.H205= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs756699810, COSV58674834; called by muse, mutect2, varscan2
- SALL3 | c.2403C>T p.D801= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs747303117, COSV101610079; called by muse, mutect2, varscan2
- SCN10A | c.225C>T p.I75= | Silent (SNP) | VAF 59/181 reads (33%) | catalogued as rs771128445, COSV71861193; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLIT3 | c.3267C>T p.C1089= | Silent (SNP) | VAF 84/287 reads (29%) | catalogued as rs1380002194, COSV100270630; called by muse, mutect2, varscan2
- SPATA16 | c.975G>A p.S325= | Silent (SNP) | VAF 64/198 reads (32%) | catalogued as rs375612371; called by muse, mutect2, varscan2
- SPATA31D1 | c.486G>A p.S162= | Silent (SNP) | VAF 87/302 reads (29%) | catalogued as rs575416308, COSV61194177; called by muse, mutect2, varscan2
- SPOCD1 | c.2943G>T p.L981= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV99930448; called by muse, mutect2, varscan2
- ST8SIA5 | c.924G>A p.A308= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV59329882, COSV59330576; called by muse, mutect2, varscan2
- TENM2 | c.3885C>T p.P1295= (on ENST00000518659 / NM_001122679.2; = p.P1056= on NM_001080428.3) | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs755258151, COSV69126811; called by muse, mutect2, varscan2
- TLN2 | c.174G>A p.P58= | Silent (SNP) | VAF 40/124 reads (32%) | catalogued as rs759137070, COSV100170317; called by muse, mutect2, varscan2
- TRHDE | c.405G>A p.P135= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99673045; called by muse, mutect2, varscan2
- TTC25 | c.1020G>T p.L340= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV101103088; called by muse, mutect2, varscan2
- WSCD1 | c.1233C>T p.H411= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs779243628, COSV100496882; called by muse, mutect2, varscan2
- ZNF362 | c.1008C>T p.N336= | Silent (SNP) | VAF 85/301 reads (28%) | catalogued as rs1156926854, COSV100987083; called by muse, mutect2, varscan2
- MAP2 | c.5074-2091C>A | Intron (SNP) | VAF 33/121 reads (27%) | catalogued as COSV52283972; called by muse, mutect2, varscan2
